HCMI case HCM-WCMC-0785-C67 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bladder. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b655b06f-fd1e-4e55-b9e0-d8181ab8f7a5

Demographics
Sex at birth: male; Race: white; Year of birth: 1961; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, intestinal type: ICD-O-3 morphology code: 8144/3; ICD-10 code: C67.8; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Overlapping lesion of bladder; Classification of tumor: primary; Age at diagnosis: 57.3 years (20,930 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IV; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: M1b; AJCC pathologic stage: Stage IV; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; Sites of involvement: Lung, NOS.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 1; Lymphatic invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFOX; Days to treatment start: 61 days; Days to treatment end: 656 days (1.8 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 509 days (1.4 years); Days to treatment end: 656 days (1.8 years).
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 627 days (1.7 years); Days to treatment end: 633 days (1.7 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 0 days.
- Days to follow up: 991 days (2.7 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 194.

Molecular and laboratory tests
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 74.2 kg; Height: 180.3 cm; BMI: 23.
- Timepoint category: Prior to Diagnosis; Comorbidities: Urinary Tract Infection; Risk factors: Urinary Tract Infection.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol drinks per day: 1; Alcohol days per week: 3.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-WCMC-0785-C67-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-WCMC-0785-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 12.
